Somatic mutation profile of tumor specimen 0DRO3X from CCDI case PBCGVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Angiomatoid fibrous histiocytoma; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 7.3 years (2,669 days).
Specimen 0DRO3X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 024c2c02-d7aa-4526-9c76-f91746bdf65d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRO3L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81034509-6cfe-48ad-8cae-092e6906fd90

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JPH1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs756673688; called by muse, mutect2, varscan2
- PLCB2 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 96/522 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TTC28 | c.1126T>C p.C376R | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IRX2 | c.1398C>T p.G466= | Silent (SNP) | VAF 16/466 reads (3%) | catalogued as rs1282541469, COSV57411253; called by muse, mutect2
